Somatic mutation profile of tumor specimen MMRF_2038_1_BM_CD138pos (aliquot MMRF_2038_1_BM_CD138pos_T1_KBS5U_L07209) from MMRF case MMRF_2038, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 37.4 years (13,675 days).
Specimen MMRF_2038_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 16f15ec0-845e-4eab-a40c-0dad929a1cd6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2038_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2038_1_PB_Whole_C2_KBS5U_L07210; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a22cf6f0-0c1c-4688-bb34-d0a20a712c1b

The open-access MAF lists 53 somatic variants for this specimen: 21 protein-altering or splice-affecting, 4 silent, 28 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, 3'UTR 14, Intron 7, Silent 4, 5'UTR 3, RNA 2, Splice Site 1, Nonsense Mutation 1, 5'Flank 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABAT | c.1282C>A p.Q428K | Missense Mutation (SNP) | VAF 33/35 reads (94%) | SIFT tolerated (0.48); PolyPhen benign (0.011); catalogued as COSV51624982; called by muse, mutect2, varscan2
- IGLV2-23 | c.320A>T p.Y107F | Missense Mutation (SNP) | VAF 46/46 reads (100%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.975); catalogued as rs572911032; called by muse, mutect2, varscan2
- IGLV3-25 | c.238T>A p.F80I | Missense Mutation (SNP) | VAF 137/139 reads (99%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as rs561016774; called by muse, mutect2, varscan2
- LIPA | c.379C>T p.R127W | Missense Mutation (SNP) | VAF 65/147 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs140686447; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OBSCN | c.17800C>T p.P5934S | Missense Mutation (SNP) | VAF 22/268 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as COSV52736878; called by muse, mutect2
- OR6Q1 | c.173G>A p.R58Q | Missense Mutation (SNP) | VAF 131/212 reads (62%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs774364450, COSV56932207; called by muse, mutect2, varscan2
- PATJ | c.1260+1G>A p.X420_splice | Splice Site (SNP) | VAF 63/130 reads (48%) | catalogued as rs1363347998; called by muse, mutect2, varscan2
- PZP | c.4C>T p.R2W | Missense Mutation (SNP) | VAF 78/150 reads (52%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs370932887, COSV54365103; called by muse, mutect2, varscan2
- VWF | c.1051G>A p.V351M | Missense Mutation (SNP) | VAF 54/100 reads (54%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as rs535978867, CD1211913; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRINP1 | c.1513T>G p.F505V | Missense Mutation (SNP) | VAF 167/346 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- C11orf80 | c.795G>A p.M265I | Missense Mutation (SNP) | VAF 40/189 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.187); called by muse, mutect2, varscan2
- CASKIN2 | c.2300C>T p.A767V | Missense Mutation (SNP) | VAF 41/110 reads (37%) | SIFT tolerated (0.45); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- CCDC88A | c.461C>A p.A154E | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2
- DCAF5 | c.215G>A p.G72E | Missense Mutation (SNP) | VAF 44/112 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- DKK4 | c.215G>A p.R72K | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- EIF4A2 | c.1141G>A p.D381N | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- GSX1 | c.590A>G p.N197S | Missense Mutation (SNP) | VAF 47/119 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MBNL1 | c.589G>A p.E197K | Missense Mutation (SNP) | VAF 137/221 reads (62%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- PRPF8 | c.3083A>G p.Y1028C | Missense Mutation (SNP) | VAF 42/94 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- TSEN15 | c.104C>A p.P35H | Missense Mutation (SNP) | VAF 29/59 reads (49%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.853); called by muse, mutect2, varscan2
- ZNF222 | c.304C>T p.Q102* | Nonsense Mutation (SNP) | VAF 25/359 reads (7%) | called by muse, mutect2
- A2M | c.4308T>C p.D1436= | Silent (SNP) | VAF 48/139 reads (35%) | catalogued as rs976898073; called by muse, mutect2, varscan2
- IGLV3-21 | c.189G>A p.V63= | Silent (SNP) | VAF 77/80 reads (96%) | catalogued as rs375188340; called by muse, mutect2
- IGLV3-22 | c.162C>T p.Y54= | Silent (SNP) | VAF 171/174 reads (98%) | called by muse, mutect2, varscan2
- IGLV3-22 | c.315C>T p.Y105= | Silent (SNP) | VAF 158/163 reads (97%) | catalogued as rs373683944; called by muse, mutect2, varscan2
- AC235097.1 | n.263T>G | RNA (SNP) | VAF 62/205 reads (30%) | called by muse, mutect2, varscan2
- ACTRT1 | c.-107T>G | 5'UTR (SNP) | VAF 45/78 reads (58%) | called by muse, mutect2, varscan2
- ANXA1 | c.706+21C>A | Intron (SNP) | VAF 45/202 reads (22%) | called by muse, mutect2, varscan2
- ARMH4 | c.*686A>G | 3'UTR (SNP) | VAF 29/55 reads (53%) | called by muse, mutect2, varscan2
- CFAP20DC | c.-309C>T | 5'UTR (SNP) | VAF 27/86 reads (31%) | catalogued as rs1401882842; called by muse, mutect2, varscan2
- CMKLR1 | c.*2496C>A | 3'UTR (SNP) | VAF 52/110 reads (47%) | called by muse, mutect2, varscan2
- CREBZF | c.-89G>A | 5'UTR (SNP) | VAF 34/107 reads (32%) | called by muse, mutect2, varscan2
- ELOVL7 | c.*818del | 3'UTR (DEL) | VAF 49/180 reads (27%) | called by mutect2, pindel, varscan2
- ELOVL7 | c.*607G>T | 3'UTR (SNP) | VAF 43/139 reads (31%) | called by muse, mutect2, varscan2
- FAM131C | c.*652G>T | 3'UTR (SNP) | VAF 32/143 reads (22%) | called by muse, mutect2, varscan2
- GBGT1 | c.137+16G>A | Intron (SNP) | VAF 8/55 reads (15%) | called by muse, mutect2, varscan2
- HECTD4 | c.11780-24G>C | Intron (SNP) | VAF 15/27 reads (56%) | called by muse, mutect2, varscan2
- HPSE | c.*255T>C | 3'UTR (SNP) | VAF 18/35 reads (51%) | catalogued as rs1219584984; called by muse, mutect2
- KCNK3 | c.*68G>T | 3'UTR (SNP) | VAF 14/23 reads (61%) | called by muse, mutect2, varscan2
- KMT2A | c.432+12154T>C | Intron (SNP) | VAF 36/125 reads (29%) | called by muse, mutect2, varscan2
- LNPEP | c.*2442T>C | 3'UTR (SNP) | VAF 30/99 reads (30%) | called by muse, mutect2, varscan2
- MAP3K8 | c.336+153del | Intron (DEL) | VAF 60/141 reads (43%) | called by mutect2, varscan2
- MIR200B | n.86G>A | RNA (SNP) | VAF 26/52 reads (50%) | called by muse, mutect2, varscan2
- MMGT1 | c.*650C>T | 3'UTR (SNP) | VAF 23/72 reads (32%) | called by muse, mutect2, varscan2
- PGGT1B | c.*774A>T | 3'UTR (SNP) | VAF 124/356 reads (35%) | catalogued as rs1310064313; called by muse, varscan2
- PSMD9 | c.242-235G>A | Intron (SNP) | VAF 25/63 reads (40%) | called by muse, mutect2, varscan2
- PSMF1 | c.*1348G>A | 3'UTR (SNP) | VAF 7/115 reads (6%) | called by muse, mutect2
- SH3TC2 | c.*530C>T | 3'UTR (SNP) | VAF 32/54 reads (59%) | called by muse, mutect2, varscan2
- SIRPB2 | c.451+93A>G | Intron (SNP) | VAF 11/21 reads (52%) | called by muse, mutect2, varscan2
- SLITRK4 | chrX:143626785 G>A | 3'Flank (SNP) | VAF 4/70 reads (6%) | catalogued as rs782037231, COSV62022223; called by muse, mutect2
- TMSB4X | chrX:12975291 G>A | 5'Flank (SNP) | VAF 88/167 reads (53%) | catalogued as COSV66081659; called by muse, mutect2, varscan2
- TRIM35 | c.*2443A>G | 3'UTR (SNP) | VAF 14/31 reads (45%) | catalogued as rs535212859; called by muse, mutect2, varscan2
- YIPF6 | c.*3416A>C | 3'UTR (SNP) | VAF 22/45 reads (49%) | called by muse, mutect2, varscan2
